Somatic mutation profile of tumor specimen TARGET-20-PASMPC-03A (aliquot TARGET-20-PASMPC-03A-01D) from TARGET case TARGET-20-PASMPC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,600 days).
Specimen TARGET-20-PASMPC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e505b335-2d48-4d7c-86ae-d07168054651.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASMPC-14A (Bone Marrow Normal), aliquot TARGET-20-PASMPC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45f09d71-b991-45d0-a3e8-b3aec875c112

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 44/196 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- KIT | c.2466T>A p.N822K | Missense Mutation (SNP) | VAF 34/196 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, varscan2
- IKZF1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58791898; called by muse, mutect2, varscan2
- TJP3 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
